Somatic mutation profile of tumor specimen TCGA-AP-A1DV-01A (aliquot TCGA-AP-A1DV-01A-21D-A135-09) from TCGA case TCGA-AP-A1DV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.0 years (21,901 days).
Specimen TCGA-AP-A1DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71b8589f-56e1-4ed4-9899-afb27661e6d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DV-10A (Blood Derived Normal), aliquot TCGA-AP-A1DV-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fa96995-67f7-4f09-8fda-2cb6db742cd1

The open-access MAF lists 14,179 somatic variants for this specimen: 10,612 protein-altering or splice-affecting, 3,223 silent, 344 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9,413, Silent 3,223, Nonsense Mutation 914, Splice Site 160, Intron 142, RNA 101, Splice Region 94, 3'UTR 34, 5'Flank 25, 3'Flank 23, 5'UTR 19, Frame Shift Ins 17.

Variants (750 of 14,179; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777902199, CM060764, COSV64971414; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGTPBP1 | c.2752C>T p.R918W (on ENST00000357081 / NM_001330701.2; = p.R878W on NM_015239.2) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564035967; ClinVar: pathogenic; called by muse, varscan2
- AMHR2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs137853104, CM016199, COSV99143488; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANO3 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1478393931, COSV56797571; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.796); catalogued as rs143040492, CM940093, CM973708, CM980115, COSV65957981; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.5929C>T p.R1977* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | catalogued as rs797045283, CM1310772, COSV51666367; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1C | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as rs730880056; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CAV3 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs116840795, CM040985, COSV57480720; ClinVar: likely pathogenic / not provided / uncertain significance; called by muse, mutect2, varscan2
- CDH23 | c.4021G>A p.D1341N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908351, CM030204; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDK10 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs772157816, CM1512661, COSV57045614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CEP250 | c.3463C>T p.R1155* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as rs749314857, CM146344, COSV100699053; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CIC | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50590933, COSV99360194; called by muse, mutect2, varscan2
- CLDN16 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs765256758, CM015915, COSV53228629, COSV99290296; ClinVar: pathogenic; called by muse, varscan2
- CLDN19 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs118203979, CM065087; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 36/70 reads (51%) | catalogued as rs375737772, CM165869, COSV58591152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs886037684, CM161670, COSV58617147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4520G>A p.G1507D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs794728225, CM157690; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGD1 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs137853264, CM002775, COSV64308119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GBE1 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs80338673, CM993166, COSV70099315; ClinVar: pathogenic; called by muse, varscan2
- GNE | c.922C>T p.R308C (on ENST00000396594 / NM_001128227.3; = p.R277C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs762106720, CM086833, CM139083, COSV64951631; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- IL17RA | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519079, COSV60053783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IMPDH1 | c.673G>A p.D225N (on ENST00000470772 / NM_001142573.2; = p.D311N on NM_000883.4) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs121912550, CM020283; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INF2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1566778651, CM113751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- LAMA2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as rs1303773212, COSV70342690; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- MEIS2 | c.905C>T p.P302L (on ENST00000561208 / NM_170675.5; = p.P289L on NM_002399.3) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064793383, COSV54931676, COSV54941335; ClinVar: likely pathogenic; called by muse, varscan2
- MOCS1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893969, CM981300, COSV57933999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MPL | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763568293, CM055993, COSV65244793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTHFD1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141210410, CM116771; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTRR | c.1850+1G>A p.X617_splice (on ENST00000264668; = p.X590_splice on NM_002454.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as rs778738842; ClinVar: likely pathogenic; called by muse, varscan2
- MYL2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs104894368, CM961005, COSV57405974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1392+1G>A p.X464_splice | Splice Site (SNP) | VAF 32/79 reads (41%) | catalogued as rs267604791, CS041541, CS1311506, COSV62202943, COSV62227804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP3 | c.3619C>T p.R1207* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as rs780020801, CM139045, COSV100447210, COSV58627688; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POMT2 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs368817785; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRPS1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1556300621; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554898067, CM1111457, COSV64291669, COSV64295080, COSV64295612; ClinVar: uncertain significance; called by muse, varscan2
- RAD50 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370769989, COSV54748170; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RPL21 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as rs587777527, CM115086, COSV55388511; ClinVar: pathogenic; called by muse, varscan2
- RPL35A | c.118_119del p.E40Ifs*12 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs1560120302; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- RUNX1 | c.877C>T p.R293* (on ENST00000344691 / NM_001001890.3; = p.R320* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 62/72 reads (86%) | catalogued as rs1569008655, CM086912, COSV55867803; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SCN5A | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs199473172, CM100679; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SGCB | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs1013015106, COSV67340757; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SHROOM4 | c.3266C>T p.S1089L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs121434620, CM060294, COSV56795744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOD1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs121912459, CM011009; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TAB2 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as rs1554263321; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- TH | c.698G>A p.R233H (on ENST00000381178 / NM_199292.3; = p.R202H on NM_000360.4) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80338892, CM981919, COSV60768810; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMCO1 | c.616C>T p.R206* (on ENST00000612311 / NM_001256164.1; = p.R155* on NM_019026.6) | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as rs765379963, COSV100903179, COSV63319044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039442, CM013068, COSV53202707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRAPPC11 | c.3193C>T p.R1065* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs750976634, COSV58215661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPS1 | c.2854C>T p.R952C (on ENST00000220888 / NM_001330599.2; = p.R965C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs28939069, CM040268, COSV55228014; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.85447G>T p.E28483* (on ENST00000591111; = p.E21059* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as rs1553539995, COSV59918596, COSV60071705; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.42769C>T p.R14257* (on ENST00000591111; = p.R6833* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs775186117, CM1514720, COSV59899605, COSV60000160; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UQCRB | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as rs1554577679, COSV54629098; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UQCRFS1 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 49/115 reads (43%) | catalogued as rs1242465339; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WNT7A | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs104893832, CM063229, COSV99541278; ClinVar: pathogenic; called by muse, varscan2
- WT1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1037084691, CM148987, COSV60067835, COSV60069216, COSV60071337, COSV60072267; ClinVar: pathogenic; called by muse, varscan2
- A1CF | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 49/112 reads (44%) | catalogued as rs371633684; called by muse, mutect2, varscan2
- A2M | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as rs777212761; called by mutect2, varscan2
- AADACL2 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 33/55 reads (60%) | catalogued as rs200370690, COSV62929953; called by muse, mutect2, varscan2
- AADACL3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs748929112, COSV100206829, COSV60198875; called by muse, mutect2, varscan2
- AADACL4 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879498; called by muse, mutect2, varscan2
- AASS | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.227); catalogued as rs117830956, COSV62789661; called by muse, mutect2, varscan2
- AASS | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100741766, COSV62789138; called by muse, mutect2, varscan2
- ABCA1 | c.6590G>A p.S2197N | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66068796; called by muse, mutect2, varscan2
- ABCA1 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1447152912; called by muse, mutect2, varscan2
- ABCA1 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs763060795; called by muse, mutect2, varscan2
- ABCA10 | c.1258G>T p.G420* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99288377; called by muse, mutect2, varscan2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, mutect2
- ABCA12 | c.4249C>T p.R1417W (on ENST00000272895 / NM_173076.3; = p.R1099W on NM_015657.3) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146331985; called by muse, mutect2, varscan2
- ABCA12 | c.2725G>A p.D909N (on ENST00000272895 / NM_173076.3; = p.D591N on NM_015657.3) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as rs767059932, COSV55963360; called by muse, mutect2, varscan2
- ABCA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762065937, CM130513, COSV55948982; called by muse, varscan2
- ABCA13 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101329889; called by muse, mutect2, varscan2
- ABCA13 | c.7274G>T p.R2425I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV71284930; called by muse, mutect2, varscan2
- ABCA13 | c.9598G>A p.A3200T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs554553164; called by muse, mutect2, varscan2
- ABCA13 | c.14539G>A p.E4847K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs267601532, COSV68943207; called by muse, mutect2, varscan2
- ABCA2 | c.1237G>A p.A413T (on ENST00000614293; = p.A383T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as rs1305446313; called by muse, mutect2, varscan2
- ABCA4 | c.6136G>A p.E2046K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV64670928; called by muse, mutect2, varscan2
- ABCA4 | c.2653G>T p.G885W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1253585396; called by muse, varscan2
- ABCA4 | c.2202C>A p.F734L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV64675508; called by muse, mutect2, varscan2
- ABCA5 | c.820A>C p.I274L | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs1301818193; called by muse, varscan2
- ABCA6 | c.2882G>T p.R961I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1568009470; called by muse, mutect2, varscan2
- ABCA6 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.217); catalogued as rs756546789, COSV104371215; called by muse, mutect2, varscan2
- ABCA6 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99446997; called by muse, varscan2
- ABCA7 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs751607002; called by muse, mutect2, varscan2
- ABCB1 | c.3307C>T p.R1103* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs1470273650, COSV99711973; called by muse, mutect2, varscan2
- ABCB1 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as rs147487745; called by muse, mutect2, varscan2
- ABCB1 | c.2263T>C p.F755L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.568); catalogued as COSV55962205; called by muse, mutect2, varscan2
- ABCB1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1390637727, COSV55944962; called by muse, mutect2, varscan2
- ABCB10 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as rs752541040, COSV100747966; called by muse, mutect2, varscan2
- ABCB5 | c.1382G>A p.R461Q (on ENST00000404938 / NM_001163941.2; = p.R16Q on NM_178559.6) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs201067658; called by muse, mutect2, varscan2
- ABCB7 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99504200; called by muse, mutect2, varscan2
- ABCB8 | c.2050G>A p.D684N (on ENST00000297504 / NM_001282291.2; = p.D667N on NM_007188.5) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774836585, COSV52510751; called by muse, varscan2
- ABCC1 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs763841979, COSV60687178; called by muse, mutect2, varscan2
- ABCC1 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs371062976; called by muse, mutect2, varscan2
- ABCC12 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60912110; called by muse, mutect2, varscan2
- ABCC4 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV65309555; called by muse, mutect2, varscan2
- ABCC5 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs540293109, COSV99656706; called by muse, mutect2, varscan2
- ABCC6 | c.3458G>A p.R1153H | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs553479685; called by muse, mutect2, varscan2
- ABCD4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778062723, COSV53990914; called by muse, mutect2, varscan2
- ABCE1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV56846807; called by muse, mutect2, varscan2
- ABCF1 | c.1810C>T p.R604C (on ENST00000326195 / NM_001025091.2; = p.R566C on NM_001090.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1380066235, COSV58229191; called by muse, mutect2, varscan2
- ABCF3 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774957824, COSV53054298; called by muse, mutect2, varscan2
- ABCG1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs148193127, CM138400; called by muse, mutect2, varscan2
- ABCG8 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763680928, COSV55391134; called by muse, mutect2, varscan2
- ABHD10 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV56325078; called by muse, mutect2, varscan2
- ABHD13 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs749263953, COSV101024240, COSV65534301; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.491T>G p.F164C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); catalogued as COSV56472633, COSV99865558; called by muse, mutect2
- ABHD16B | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199801697; called by muse, mutect2, varscan2
- ABHD17A | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs779708733; called by muse, varscan2
- ABI1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs749435530, COSV104415219; called by muse, mutect2, varscan2
- ABI1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs757418866, COSV61014740; called by muse, mutect2, varscan2
- ABI3BP | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778790101; called by muse, mutect2, varscan2
- ABI3BP | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV52545552; called by muse, mutect2, varscan2
- ABL1 | c.3037C>T p.R1013W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs755821709, COSV59329904; called by muse, mutect2, varscan2
- ABL1 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1456042173, COSV59334185; called by muse, mutect2, varscan2
- ABLIM1 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs1413535860, COSV53313027; called by muse, mutect2, varscan2
- ABO | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs370138477; called by muse, mutect2, varscan2
- ABR | c.897G>A p.T299= (on ENST00000302538 / NM_021962.5; = p.T262= on NM_001092.5) | Splice Region (SNP) | VAF 37/63 reads (59%) | catalogued as rs768956905; called by muse, mutect2, varscan2
- ABR | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as rs1321990254; called by muse, mutect2, varscan2
- ABRAXAS2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV53715994, COSV53717869; called by muse, varscan2
- ABRAXAS2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as rs752407314, COSV53716596; called by muse, varscan2
- ABTB1 | c.864C>A p.A288= (on ENST00000232744 / NM_172027.3; = p.A146= on NM_032548.3) | Splice Region (SNP) | VAF 25/56 reads (45%) | catalogued as rs912361129; called by muse, mutect2, varscan2
- ABTB2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs1427981385; called by muse, mutect2, varscan2
- AC004593.2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV56089052; called by muse, mutect2, varscan2
- AC013489.1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1265060262, COSV51550247; called by muse, mutect2, varscan2
- AC100868.1 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs796855710; called by muse, mutect2, varscan2
- AC126283.2 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs763276049; called by muse, mutect2, varscan2
- AC136428.1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.103); catalogued as rs758557557; called by muse, mutect2, varscan2
- AC244197.3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1290154616; called by muse, mutect2, varscan2
- ACAA1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs776720228, COSV57182492; called by muse, mutect2, varscan2
- ACACB | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs749816455, COSV100622960; called by muse, mutect2, varscan2
- ACACB | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs763388361, COSV58130479; called by muse, mutect2, varscan2
- ACACB | c.5315C>T p.A1772V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs1198616474; called by muse, mutect2, varscan2
- ACAD11 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as COSV53895502; called by muse, mutect2, varscan2
- ACAD11 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV53893627; called by muse, mutect2, varscan2
- ACAP1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1256701079; called by muse, mutect2, varscan2
- ACAP2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1251813082, COSV58755489; called by muse, mutect2, varscan2
- ACBD3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs374978330; called by muse, mutect2, varscan2
- ACE2 | c.1309A>C p.N437H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314469120; called by muse, mutect2, varscan2
- ACMSD | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs939826275, COSV51607557; called by muse, mutect2, varscan2
- ACO2 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781117483; called by mutect2, varscan2
- ACOT8 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747087835, COSV54168584; called by muse, mutect2, varscan2
- ACSL1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as rs1160474463; called by muse, varscan2
- ACSL5 | c.445G>A p.E149K (on ENST00000354273; = p.E205K on NM_016234.3) | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs1023317855, COSV61133915; called by muse, mutect2, varscan2
- ACSM4 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs201026673; called by muse, varscan2
- ACSM5 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs141553052; called by muse, mutect2, varscan2
- ACSM5 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755627565; called by muse, mutect2
- ACSS1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as rs376591574; called by muse, mutect2, varscan2
- ACTA1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as CM151674; called by muse, mutect2, varscan2
- ACTA1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.161); catalogued as COSV64203495; called by muse, mutect2, varscan2
- ACTG1 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs11549231, COSV59511621; called by muse, mutect2, varscan2
- ACTL7B | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1260635143, COSV65927750; called by muse, varscan2
- ACTN1 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs547204209, COSV99518298; called by muse, mutect2, varscan2
- ACTN1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs373084944; called by muse, mutect2, varscan2
- ACTN1 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs904887313, COSV51994919; called by muse, mutect2, varscan2
- ACTN2 | c.786C>T p.A262= | Splice Region (SNP) | VAF 22/41 reads (54%) | catalogued as rs201636760; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTR3 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99603938; called by muse, mutect2, varscan2
- ACTR5 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.928); catalogued as rs367988045; called by muse, mutect2, varscan2
- ACTR6 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as rs776326760, COSV104386661; called by muse, varscan2
- ACTR6 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs1253396208, COSV51841209; called by muse, mutect2, varscan2
- ACVR2B | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61702898; called by muse, mutect2, varscan2
- ADAM19 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); catalogued as rs199716249, COSV57426292; called by muse, mutect2, varscan2
- ADAM19 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs747691760, COSV57424621; called by muse, mutect2, varscan2
- ADAM21 | c.1515G>T p.K505N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV50789053; called by muse, mutect2, varscan2
- ADAM22 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369078128; called by muse, mutect2, varscan2
- ADAM7 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0.031); catalogued as COSV51548136; called by muse, mutect2, varscan2
- ADAM7 | c.2003-1G>T p.X668_splice | Splice Site (SNP) | VAF 76/151 reads (50%) | catalogued as COSV99443659; called by muse, varscan2
- ADAMTS1 | c.2429G>T p.R810I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as rs1275756719; called by muse, mutect2, varscan2
- ADAMTS12 | c.1447G>T p.G483* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV61262255; called by muse, mutect2, varscan2
- ADAMTS14 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1257663269; called by muse, mutect2, varscan2
- ADAMTS14 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs754471674; called by muse, mutect2, varscan2
- ADAMTS18 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs774713566, COSV51406679; called by muse, mutect2, varscan2
- ADAMTS19 | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as rs571986172, COSV50799260; called by muse, mutect2, varscan2
- ADAMTS3 | c.3570G>T p.K1190N | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as COSV54399798; called by muse, mutect2, varscan2
- ADAMTS3 | c.2953G>T p.G985* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs1290277459, COSV54394049; called by muse, varscan2
- ADAMTS3 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs559836113, COSV54392837; called by mutect2, varscan2
- ADAMTS3 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs755116141, COSV54389887; called by muse, mutect2, varscan2
- ADAMTS6 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.433); catalogued as COSV66862194; called by muse, mutect2, varscan2
- ADAMTS7 | c.3935C>T p.P1312L | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs770827049; called by muse, mutect2, varscan2
- ADAMTS8 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs749975173, COSV99960877; called by muse, mutect2, varscan2
- ADAMTS8 | c.721-1G>T p.X241_splice | Splice Site (SNP) | VAF 6/11 reads (55%) | catalogued as COSV57292633; called by muse, mutect2, varscan2
- ADAMTS9 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs373729997; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1370G>T p.R457I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52813377; called by muse, mutect2, varscan2
- ADAMTSL4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs201047866; called by muse, mutect2, varscan2
- ADAMTSL4 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs146358482; called by mutect2, varscan2
- ADCY1 | c.2627A>G p.N876S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52040941; called by muse, mutect2, varscan2
- ADCY3 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs148445836; called by muse, mutect2, varscan2
- ADCY6 | c.1421G>A p.G474D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173766687; called by muse, mutect2, varscan2
- ADCY8 | c.3581C>T p.A1194V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as rs773491638, COSV53897305, COSV53908386; called by muse, mutect2, varscan2
- ADCY8 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs751806556, COSV53920771; called by muse, mutect2, varscan2
- ADD1 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1225499433; called by muse, mutect2, varscan2
- ADD2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558526530, COSV52456622, COSV52462275; called by muse, mutect2
- ADD2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781842295, COSV52458987; called by muse, mutect2, varscan2
- ADGRA1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs199841510, COSV66925412; called by muse, mutect2, varscan2
- ADGRA1 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs542967776, COSV66926478; called by muse, mutect2, varscan2
- ADGRA2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139041191, COSV59445991; called by muse, mutect2, varscan2
- ADGRA3 | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs774357237, COSV51560877; called by muse, mutect2, varscan2
- ADGRB1 | c.3734G>A p.R1245H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1168368243; called by muse, mutect2
- ADGRB3 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs922398016, COSV65388803; called by muse, mutect2, varscan2
- ADGRB3 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65400377; called by muse, varscan2
- ADGRB3 | c.3527C>T p.S1176L | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs142863825, COSV53234039; called by muse, mutect2, varscan2
- ADGRD1 | c.2549G>A p.G850D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as rs1211650690; called by muse, mutect2, varscan2
- ADGRE1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1194991100, COSV51672107; called by muse, mutect2, varscan2
- ADGRE3 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs149254238, COSV99506422; called by muse, mutect2, varscan2
- ADGRE3 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV53728256; called by muse, mutect2, varscan2
- ADGRF3 | c.3109C>T p.R1037C (on ENST00000311519 / NM_001145168.1; = p.R838C on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1278140623, COSV61051496; called by muse, mutect2, varscan2
- ADGRF3 | c.2644G>A p.V882I (on ENST00000311519 / NM_001145168.1; = p.V683I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1206165540; called by muse, mutect2, varscan2
- ADGRF3 | c.376G>A p.V126I (on ENST00000311519 / NM_001145168.1; = p.V67I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs757218422, COSV61049939; called by muse, mutect2, varscan2
- ADGRF5 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs199931272, COSV51940547; called by muse, mutect2, varscan2
- ADGRG4 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV54955452; called by muse, mutect2, varscan2
- ADGRG4 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs754146292; called by muse, mutect2, varscan2
- ADGRG4 | c.5879C>A p.S1960Y | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99794421; called by muse, mutect2, varscan2
- ADGRG6 | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99749616; called by muse, mutect2, varscan2
- ADGRL2 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746200328, COSV54660115; called by muse, mutect2, varscan2
- ADGRL2 | c.2846G>T p.R949M (on ENST00000370717 / NM_001366005.1; = p.R936M on NM_012302.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54683299; called by muse, mutect2, varscan2
- ADGRL3 | c.875G>A p.R292H (on ENST00000506720 / NM_001322402.2; = p.R224H on NM_015236.6) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747554116, COSV72269499; called by muse, mutect2, varscan2
- ADGRV1 | c.13577C>A p.S4526Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as rs1280697053, COSV67979460; called by muse, mutect2
- ADGRV1 | c.15262G>T p.E5088* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV67980148; called by muse, mutect2, varscan2
- ADH1C | c.656G>T p.R219I | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV72463426; called by muse, mutect2, varscan2
- ADHFE1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs373699840; called by muse, varscan2
- ADNP2 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs772902577; called by muse, mutect2, varscan2
- ADNP2 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs377757808; called by muse, mutect2, varscan2
- ADPRH | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.308); catalogued as rs1170835446; called by muse, varscan2
- ADRA1A | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV52366575, COSV99372034; called by muse, mutect2, varscan2
- ADRA1A | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52360029; called by muse, mutect2, varscan2
- ADRA1A | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1010863998; called by muse, mutect2, varscan2
- ADRA1B | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as rs1328289918; called by muse, mutect2, varscan2
- AEBP1 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs111888664; called by muse, mutect2, varscan2
- AFDN | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs770737214, COSV60044055; called by muse, mutect2, varscan2
- AFF2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs1557256430, COSV60664395, COSV60668509; called by muse, mutect2, varscan2
- AFF2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.137); catalogued as rs963831686; called by muse, mutect2, varscan2
- AFF3 | c.1859T>C p.V620A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1166693726; called by muse, mutect2
- AFF3 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57852223; called by muse, mutect2, varscan2
- AFF4 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as COSV54793570; called by muse, mutect2, varscan2
- AFG1L | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186962719; called by muse, mutect2, varscan2
- AFM | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV56919366; called by muse, mutect2, varscan2
- AFTPH | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1280487180, COSV53218947; called by muse, varscan2
- AGAP1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58325321; called by muse, mutect2, varscan2
- AGBL1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs145790658; called by muse, mutect2, varscan2
- AGBL1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66876919; called by muse, mutect2, varscan2
- AGL | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs369044372, COSV104398775; called by muse, mutect2, varscan2
- AGMO | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV61109625; called by muse, mutect2, varscan2
- AGO2 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1205353566, COSV99596260; called by muse, mutect2, varscan2
- AGO4 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.586); catalogued as rs376006576; called by muse, mutect2, varscan2
- AGPAT4 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV57243767; called by muse, mutect2, varscan2
- AGPS | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99931272; called by muse, mutect2, varscan2
- AGR3 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100123827; called by muse, mutect2, varscan2
- AGT | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV64185334; called by muse, mutect2, varscan2
- AGT | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs567719599, COSV100794172; called by muse, varscan2
- AGTPBP1 | c.2729G>A p.R910H (on ENST00000357081 / NM_001330701.2; = p.R870H on NM_015239.2) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61270790; called by muse, varscan2
- AGTPBP1 | c.2620C>T p.R874W (on ENST00000357081 / NM_001330701.2; = p.R834W on NM_015239.2) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1418982979, COSV61270623; called by muse, mutect2, varscan2
- AGTPBP1 | c.2072G>A p.R691H (on ENST00000357081 / NM_001330701.2; = p.R651H on NM_015239.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as rs760554628; called by mutect2, varscan2
- AGTR1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200184769, COSV62557211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHCTF1 | c.6760C>T p.R2254W (on ENST00000366508; = p.R2228W on NM_015446.5) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs758346249, COSV58248341; called by muse, mutect2, varscan2
- AHDC1 | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs962169806, COSV55942999; called by muse, mutect2, varscan2
- AHNAK2 | c.15706C>A p.L5236I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as COSV60908405, COSV60911622; called by muse, mutect2, varscan2
- AHSG | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99889960; called by muse, mutect2, varscan2
- AIFM1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs747871895, COSV54852707; called by muse, mutect2, varscan2
- AIMP1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 26/45 reads (58%) | catalogued as rs373122636; called by muse, mutect2, varscan2
- AIMP1 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs1406124387; called by muse, mutect2, varscan2
- AIMP2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.505); catalogued as rs372238513, COSV52239883; called by muse, mutect2, varscan2
- AJAP1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100981455; called by muse, mutect2
- AJAP1 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776328155; called by muse, varscan2
- AK5 | c.769C>T p.R257C (on ENST00000354567 / NM_174858.3; = p.R231C on NM_012093.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745816196; called by muse, mutect2, varscan2
- AK7 | c.716C>A p.A239E | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99967565; called by muse, mutect2, varscan2
- AK8 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773353352; called by mutect2, varscan2
- AK8 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV53754113; called by mutect2, varscan2
- AKAP12 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs970522287; called by muse, varscan2
- AKAP13 | c.6598C>T p.R2200C (on ENST00000394518 / NM_007200.5; = p.R2204C on NM_006738.6) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63450117; called by muse, mutect2, varscan2
- AKAP17A | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777749470; called by muse, varscan2
- AKAP17A | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100002461; called by muse, mutect2
- AKAP6 | c.5086G>A p.E1696K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1469892841, COSV55225828; called by muse, mutect2, varscan2
- AKAP8 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773531995; called by muse, mutect2, varscan2
- AKAP8L | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs766116652; called by muse, mutect2, varscan2
- AKAP9 | c.9952C>T p.R3318* (on ENST00000359028; = p.R3294* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs145355395; called by muse, varscan2
- AKAP9 | c.11419C>T p.R3807* (on ENST00000359028; = p.R3783* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as rs376277241; called by muse, mutect2, varscan2
- AKR1A1 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1286691295; called by muse, mutect2, varscan2
- AKR1B15 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs373511828; called by muse, mutect2, varscan2
- AKR1C3 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs190674338; called by muse, mutect2, varscan2
- AL031777.2 | c.385+1G>A p.X129_splice | Splice Site (SNP) | VAF 47/109 reads (43%) | catalogued as rs1380583736; called by muse, mutect2, varscan2
- AL133500.1 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); catalogued as COSV99860507; called by muse, mutect2, varscan2
- AL136295.1 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1325020813; called by muse, mutect2, varscan2
- AL645922.1 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as rs1229029793, COSV100191522; called by muse, mutect2, varscan2
- ALDH1A2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.174); catalogued as rs1283761840, COSV51078204; called by muse, varscan2
- ALDH1A3 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as rs772610695, COSV60900907, COSV60903325; called by muse, mutect2, varscan2
- ALDH1L1 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs550440307, COSV56410533, COSV56414628; called by muse, mutect2, varscan2
- ALDH1L1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs138191102; called by muse, mutect2, varscan2
- ALDH5A1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs374232934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG10 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV56793947; called by muse, mutect2, varscan2
- ALG11 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as rs377356876; called by mutect2, varscan2
- ALG5 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53504958; called by muse, mutect2, varscan2
- ALG9 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as COSV67644331; called by muse, mutect2, varscan2
- ALK | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774951734, COSV66580669; ClinVar: uncertain significance; called by muse, mutect2
- ALKBH3 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs202134415; called by muse, mutect2, varscan2
- ALKBH3 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776707628, COSV100236314, COSV57025074; called by muse, mutect2, varscan2
- ALMS1 | c.9673C>T p.R3225C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs200215551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX12B | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1274525093, COSV100046719; called by muse, mutect2, varscan2
- AMER1 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs945869656; called by muse, mutect2, varscan2
- AMER1 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV57658987; called by muse, mutect2, varscan2
- AMFR | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs776654452, COSV51921073; called by muse, mutect2, varscan2
- AMFR | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as rs777288075; called by muse, mutect2, varscan2
- AMN1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs889986563, COSV55671992; called by muse, varscan2
- AMN1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs765159439, COSV55670682; called by muse, varscan2
- AMY2A | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs772830789; called by mutect2, varscan2
- AMZ1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.079); catalogued as rs1215507221, COSV56686077; called by muse, varscan2
- AMZ1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758185125; called by muse, mutect2, varscan2
- AMZ2 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100703151; called by muse, mutect2, varscan2
- ANAPC7 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs200412886, COSV71444075; called by muse, mutect2, varscan2
- ANGEL2 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as rs373936219; called by muse, mutect2, varscan2
- ANGPTL5 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57531935; called by muse, mutect2, varscan2
- ANGPTL8 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 40/93 reads (43%) | catalogued as rs774587241; called by muse, mutect2, varscan2
- ANK1 | c.3220G>A p.D1074N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as rs775457067, COSV55881693; called by muse, mutect2, varscan2
- ANK2 | c.3032G>A p.R1011H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563808779, COSV52144383; called by muse, mutect2, varscan2
- ANK2 | c.8725C>T p.P2909S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.776); catalogued as COSV52162583; called by muse, mutect2, varscan2
- ANK3 | c.6893C>T p.S2298L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV99779427; called by muse, mutect2, varscan2
- ANK3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55053872; called by muse, mutect2, varscan2
- ANKDD1A | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756222100, COSV60353290, COSV60354570; called by muse, mutect2, varscan2
- ANKEF1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs748415063; called by muse, mutect2, varscan2
- ANKFN1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1287743848, COSV59446410; called by muse, mutect2, varscan2
- ANKH | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs1397037846, COSV52483567, COSV99415591; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2233G>T p.G745* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV51852018, COSV99784102; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7084C>T p.R2362* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99783811; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7769C>T p.S2590F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV51842196, COSV51855420; called by muse, mutect2, varscan2
- ANKK1 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV100393074; called by muse, mutect2, varscan2
- ANKLE2 | c.1460C>A p.S487Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61707689; called by muse, mutect2, varscan2
- ANKMY1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs373716544; called by muse, mutect2, varscan2
- ANKMY1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754304844; called by muse, mutect2, varscan2
- ANKRD1 | c.346-1G>A p.X116_splice | Splice Site (SNP) | VAF 12/18 reads (67%) | catalogued as rs1447308166; called by muse, mutect2, varscan2
- ANKRD11 | c.4970C>T p.S1657L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749114664, COSV56362701; called by muse, mutect2, varscan2
- ANKRD11 | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs749473676, COSV56365478; called by muse, mutect2, varscan2
- ANKRD13A | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs771991859; called by muse, mutect2, varscan2
- ANKRD20A1 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202214101; called by muse, varscan2
- ANKRD22 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs778012114, CM142288; called by muse, varscan2
- ANKRD24 | c.3112C>T p.R1038C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs373558892; called by muse, mutect2, varscan2
- ANKRD26 | c.1808A>G p.Y603C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1000608884; called by muse, mutect2, varscan2
- ANKRD27 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs757626430; called by muse, varscan2
- ANKRD30A | c.1694C>A p.S565Y (on ENST00000611781; = p.S509Y on NM_052997.2) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs879174134, COSV64616386; called by muse, mutect2, varscan2
- ANKRD30A | c.3141A>C p.K1047N (on ENST00000611781; = p.K991N on NM_052997.2) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as rs1204511204, COSV104423910; called by muse, mutect2, varscan2
- ANKRD44 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.363); catalogued as rs779863444; called by muse, mutect2, varscan2
- ANKRD44 | c.1775A>G p.D592G | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV56556272; called by muse, mutect2, varscan2
- ANKRD44 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs925366258, COSV56567963; called by muse, mutect2, varscan2
- ANKRD45 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs764620968, COSV100322436; called by muse, varscan2
- ANKRD45 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV60962596; called by muse, varscan2
- ANKRD54 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as rs772436185, COSV53236582; called by muse, mutect2, varscan2
- ANKS1A | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.869); catalogued as rs1459947461; called by muse, varscan2
- ANKS1A | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs906953823; called by muse, varscan2
- ANKS1B | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs774006211, COSV61357354; called by muse, mutect2, varscan2
- ANO3 | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV56790495, COSV56807883; called by muse, mutect2, varscan2
- ANO4 | c.925C>T p.R309* (on ENST00000392977 / NM_001286615.2; = p.R274* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs866684439, COSV104407411, COSV54586554; called by muse, mutect2, varscan2
- ANO4 | c.2393G>A p.R798H (on ENST00000392977 / NM_001286615.2; = p.R763H on NM_178826.4) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765241694, COSV54594322; called by muse, mutect2, varscan2
- ANOS1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1176399589, COSV52918865; called by muse, mutect2, varscan2
- ANOS1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as rs894572813; called by muse, mutect2, varscan2
- ANTXR2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.677); catalogued as rs756324499, COSV56313262; called by muse, mutect2, varscan2
- ANXA10 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100829112; called by muse, mutect2, varscan2
- ANXA11 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); catalogued as COSV99626869; called by muse, mutect2, varscan2
- ANXA6 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747761940; called by muse, mutect2, varscan2
- AOAH | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV51735544; called by muse, mutect2
- AOC1 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746534662; called by muse, mutect2, varscan2
- AOC1 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs560992275, COSV62867097; called by muse, mutect2
- AP1B1 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs763283898; called by muse, mutect2, varscan2
- AP1G2 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1427295596; called by muse, mutect2, varscan2
- AP1G2 | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as rs753650407, COSV55337656; called by muse, mutect2, varscan2
- AP1G2 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as rs780673370; called by muse, mutect2, varscan2
- AP1M2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs773360506, COSV51565455; called by muse, mutect2, varscan2
- AP1S3 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as rs1372202707; called by muse, mutect2, varscan2
- AP2A1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447484112, COSV62821149; called by muse, mutect2, varscan2
- AP2A2 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59963660; called by muse, mutect2, varscan2
- AP2B1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV104387348; called by muse, mutect2, varscan2
- AP2S1 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.589); catalogued as rs756038304, COSV54384505; called by muse, mutect2, varscan2
- AP3B2 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV99916562; called by muse, varscan2
- AP3M1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142765677; called by muse, varscan2
- AP3M2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs145474181; called by muse, mutect2, varscan2
- AP3S1 | c.384G>T p.M128I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV57473538; called by muse, mutect2, varscan2
- AP4B1 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs767747484, COSV56723146; called by muse, mutect2, varscan2
- AP4B1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.733); catalogued as rs145820731; called by muse, mutect2, varscan2
- AP4B1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1454940627; called by muse, mutect2, varscan2
- APC | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs995081817; called by muse, mutect2, varscan2
- APC | c.6970C>A p.P2324T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs770250821; ClinVar: uncertain significance; called by muse, varscan2
- APCDD1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.576); catalogued as rs771909445, COSV62372830; called by muse, varscan2
- APLP1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs780081746, COSV55702835; called by muse, mutect2, varscan2
- APLP1 | c.1645C>T p.R549* (on ENST00000221891 / NM_001024807.3; = p.R548* on NM_005166.4) | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as rs776958157, COSV55701572, COSV55702466; called by muse, mutect2, varscan2
- APLP2 | c.262C>A p.L88I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53841780; called by muse, mutect2
- APMAP | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs149459666, COSV99468629; called by muse, mutect2, varscan2
- APMAP | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs776849853, COSV54174312; called by muse, mutect2, varscan2
- APOA4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as rs145184607; called by muse, mutect2, varscan2
- APOBEC3F | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs773563808, COSV100415089; called by muse, mutect2, varscan2
- APOBEC4 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1398937334; called by muse, varscan2
- APOBEC4 | c.619G>T p.G207* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as rs143188677; called by muse, varscan2
- APOC4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1331127938, COSV52990344, COSV99376950; called by muse, mutect2
- APOL1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.05); catalogued as rs763070780; called by muse, mutect2, varscan2
- APOL2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs377641018; called by muse, mutect2, varscan2
- APOL5 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs769730762, COSV50768799; called by muse, mutect2, varscan2
- APOM | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753977558; called by muse, mutect2, varscan2
- APOO | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs1255069164; called by muse, mutect2, varscan2
- APOOL | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs368247345; called by muse, mutect2, varscan2
- APPL1 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.067); catalogued as rs763244103, COSV55700821; called by muse, mutect2, varscan2
- APPL2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs748958008; called by muse, mutect2, varscan2
- APPL2 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs772110616, COSV51589334; called by muse, mutect2, varscan2
- AQP12A | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as rs1296800208; called by muse, varscan2
- AQP12A | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs576227322; called by muse, varscan2
- AQR | c.206T>G p.F69C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV104381165; called by muse, mutect2, varscan2
- AR | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM126556, COSV65958453; called by muse, mutect2, varscan2
- AR | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD942044; called by muse, mutect2, varscan2
- ARAP1 | c.2842G>A p.A948T (on ENST00000393609 / NM_001040118.2; = p.A703T on NM_015242.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1297169368, COSV61991309; called by muse, mutect2, varscan2
- ARAP1 | c.1952G>A p.R651H (on ENST00000393609 / NM_001040118.2; = p.R406H on NM_015242.4) | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs201068078; called by muse, mutect2, varscan2
- ARAP1 | c.829G>A p.D277N (on ENST00000393609 / NM_001040118.2; = p.D32N on NM_015242.4) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs775610852, COSV61994086; called by muse, mutect2, varscan2
- ARAP1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as rs933329458; called by muse, mutect2, varscan2
- ARAP2 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.51); catalogued as rs144707231; called by muse, mutect2
- ARAP2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs966987664, COSV58286766; called by muse, mutect2
- ARAP3 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.644); catalogued as rs1178016939, COSV99500337; called by muse, mutect2, varscan2
- AREL1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs1217422488; called by muse, mutect2, varscan2
- ARF1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.591); catalogued as COSV55254149; called by muse, mutect2, varscan2
- ARFGEF1 | c.5015G>A p.R1672H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs200392828, COSV51620792; called by muse, mutect2, varscan2
- ARFGEF1 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 49/112 reads (44%) | catalogued as COSV51608555; called by muse, mutect2, varscan2
- ARFGEF1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764719716, COSV51607682; called by muse, mutect2, varscan2
- ARFGEF2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1022300649, COSV64211590; ClinVar: uncertain significance; called by muse, varscan2
- ARFGEF2 | c.5116C>T p.R1706W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303771541, COSV100904563; called by muse, mutect2, varscan2
- ARFGEF3 | c.5521C>A p.L1841I | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV52454232; called by muse, mutect2, varscan2
- ARFIP1 | c.548C>T p.S183L (on ENST00000353617 / NM_001287432.1; = p.S151L on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as rs551587540; called by muse, mutect2, varscan2
- ARG2 | c.843G>T p.E281D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99373888; called by muse, mutect2, varscan2
- ARHGAP11B | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV101451784; called by muse, mutect2, varscan2
- ARHGAP15 | c.599G>T p.R200I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV54509120; called by muse, mutect2, varscan2
- ARHGAP21 | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV57601656, COSV57609108; called by muse, mutect2, varscan2
- ARHGAP22 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1231366282, COSV99984513; called by muse, mutect2, varscan2
- ARHGAP22 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754992911; called by muse, mutect2, varscan2
- ARHGAP24 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs571519833, COSV67834201; called by muse, mutect2, varscan2
- ARHGAP24 | c.2104C>T p.R702* (on ENST00000395184 / NM_001025616.3; = p.R609* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as rs376118883; called by muse, mutect2, varscan2
- ARHGAP25 | c.294G>T p.K98N (on ENST00000409202 / NM_001007231.3; = p.K91N on NM_014882.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.026); catalogued as rs1325996007, COSV54910703; called by muse, mutect2, varscan2
- ARHGAP25 | c.1312C>T p.R438C (on ENST00000409202 / NM_001007231.3; = p.R430C on NM_014882.3) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767100810, COSV54900947; called by muse, mutect2, varscan2
- ARHGAP30 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV63516492; called by muse, mutect2, varscan2
- ARHGAP30 | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV63519170; called by muse, mutect2, varscan2
- ARHGAP32 | c.3101C>T p.P1034L (on ENST00000310343 / NM_001378025.1; = p.P685L on NM_014715.4) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1211118683; called by muse, mutect2, varscan2
- ARHGAP36 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV52264412; called by muse, mutect2, varscan2
- ARHGAP36 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs1057296329; called by muse, varscan2
- ARHGAP6 | c.2018C>A p.S673Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100273536; called by muse, mutect2, varscan2
- ARHGAP6 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs770470448; called by muse, mutect2, varscan2
- ARHGDIA | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs752693120, COSV99482498; called by muse, mutect2, varscan2
- ARHGEF11 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1017809905, COSV59357611; called by muse, mutect2, varscan2
- ARHGEF17 | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs779817536, COSV55229264; called by muse, mutect2, varscan2
- ARHGEF18 | c.1911C>T p.I637= (on ENST00000359920 / NM_001130955.2; = p.I533= on NM_015318.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/114 reads (9%) | catalogued as rs1396995978; ClinVar: likely benign; called by muse, mutect2
- ARHGEF26 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as rs759124391; called by muse, mutect2, varscan2
- ARHGEF28 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032784486, COSV55254804, COSV99708932; called by muse, mutect2, varscan2
- ARHGEF3 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV56330278; called by muse, mutect2, varscan2
- ARHGEF4 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs369020916; called by muse, mutect2, varscan2
- ARID1A | c.4912G>T p.D1638Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61388301; called by muse, mutect2
- ARID1B | c.6464C>T p.T2155M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1381434956, COSV51667757; called by muse, mutect2, varscan2
- ARID2 | c.5306G>A p.R1769Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57614685; called by muse, mutect2, varscan2
- ARID4A | c.2960C>A p.S987Y | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV62165716; called by muse, mutect2, varscan2
- ARID5B | c.3437C>T p.A1146V | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs1349220963; called by muse, mutect2, varscan2
- ARIH1 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 31/59 reads (53%) | catalogued as COSV65913399; called by muse, mutect2, varscan2
- ARL2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs778402408, COSV55861782; called by muse, mutect2, varscan2
- ARMC1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); catalogued as rs763773660; called by muse, mutect2, varscan2
- ARMC2 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64551980; called by muse, mutect2, varscan2
- ARMC3 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs199547387, COSV53058095; called by muse, mutect2, varscan2
- ARMCX2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1259351624, COSV57529232; called by muse, mutect2, varscan2
- ARMH4 | c.1547G>T p.R516I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV50764013; called by muse, mutect2, varscan2
- ARPIN | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs906002880, COSV104422960; called by muse, mutect2, varscan2
- ARPP21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs535145550, COSV51792286, COSV51800995; called by muse, mutect2, varscan2
- ARR3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs372210873; called by muse, varscan2
- ARR3 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777141143; called by muse, mutect2, varscan2
- ARRDC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100603536; called by muse, mutect2
- ARRDC4 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1247827755, COSV51418426, COSV99164327; called by muse, mutect2, varscan2
- ASAH2B | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs551101710, COSV51768400; called by muse, mutect2, varscan2
- ASB1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs780761258, COSV99223421; called by muse, mutect2, varscan2
- ASB10 | c.1324C>T p.P442S (on ENST00000420175 / NM_001142459.2; = p.P427S on NM_080871.4) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as rs1458715016; called by muse, mutect2, varscan2
- ASB16 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs144140141; called by muse, mutect2, varscan2
- ASB18 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.725); catalogued as rs746968566, COSV68960620; called by muse, mutect2, varscan2
- ASB2 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60113765; called by muse, mutect2, varscan2
- ASB3 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs371519069; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASB8 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.601); catalogued as COSV100402282; called by muse, varscan2
- ASB8 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1425669993; called by muse, mutect2, varscan2
- ASB9 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 27/49 reads (55%) | catalogued as COSV66852205; called by muse, mutect2, varscan2
- ASCC3 | c.5422C>T p.R1808C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as rs748462453, COSV64977944; called by muse, mutect2, varscan2
- ASCC3 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142884762, COSV100225879; called by muse, mutect2, varscan2
- ASCC3 | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs748796029; called by muse, mutect2, varscan2
- ASCC3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138861677, COSV100225520; called by muse, varscan2
- ASCL3 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748424739, COSV57941056; called by muse, mutect2, varscan2
- ASH1L | c.8227C>T p.R2743W (on ENST00000368346 / NM_001366177.2; = p.R2738W on NM_018489.3) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64213590; called by muse, mutect2, varscan2
- ASH1L | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746450493, COSV64210433; called by muse, mutect2, varscan2
- ASIC4 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.776); catalogued as rs770046746; called by muse, mutect2, varscan2
- ASMTL | c.1126T>G p.F376V | Missense Mutation (SNP) | VAF 82/181 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV101187722; called by muse, mutect2, varscan2
- ASMTL | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371287922; called by muse, mutect2, varscan2
- ASPHD1 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.452); catalogued as rs762641417; called by muse, mutect2
- ASPM | c.9922C>T p.R3308C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772982246, COSV54125418; called by muse, mutect2, varscan2
- ASPM | c.7993C>T p.R2665C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs201881549; called by muse, mutect2, varscan2
- ASPM | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1034800662, COSV54131872; called by muse, mutect2, varscan2
- ASPM | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV54137772; called by muse, mutect2, varscan2
- ASS1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs766668660; called by muse, mutect2, varscan2
- ASTE1 | c.1305C>T p.L435= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as rs964570443; called by muse, mutect2
- ASTN1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs143274107, COSV56082666; called by muse, varscan2
- ASTN1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1294725520; called by muse, varscan2
- ASTN2 | c.1468G>A p.D490N (on ENST00000313400 / NM_001365069.1; = p.D439N on NM_014010.5) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs756643087, COSV57779489; called by muse, mutect2
- ASTN2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.973); catalogued as rs371054320, COSV57777895; called by muse, mutect2, varscan2
- ASXL2 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377352572, COSV55454592; called by muse, mutect2, varscan2
- ASXL2 | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55457655; called by muse, mutect2, varscan2
- ASXL3 | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52480344, COSV99324581; called by muse, mutect2, varscan2
- ASXL3 | c.4681G>T p.E1561* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV104368383; called by muse, mutect2, varscan2
- ATAD5 | c.2696T>G p.L899R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as rs1028729662; called by muse, mutect2, varscan2
- ATCAY | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs756334577; called by muse, mutect2, varscan2
- ATF6 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); catalogued as COSV63407369; called by muse, mutect2, varscan2
- ATF7 | c.1021G>A p.D341N (on ENST00000548446 / NM_001366555.2; = p.D330N on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs747223058, COSV60645086; called by muse, mutect2, varscan2
- ATG101 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465612076, COSV61085321; called by muse, mutect2, varscan2
- ATG14 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs560262834; called by muse, mutect2, varscan2
- ATG16L2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1362686328; called by muse, mutect2, varscan2
- ATG2B | c.6220C>T p.R2074C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778399547, COSV55890546; called by muse, mutect2, varscan2
- ATG2B | c.6044C>T p.A2015V | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200638090, COSV55892219; called by muse, mutect2, varscan2
- ATG2B | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758528785, COSV55889986; called by muse, mutect2, varscan2
- ATG2B | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV63426033; called by muse, mutect2, varscan2
- ATG4B | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1326302400; called by muse, mutect2, varscan2
- ATG4D | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs565133715, COSV100521146, COSV58762294; called by muse, mutect2, varscan2
- ATL3 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs972789399; called by muse, mutect2, varscan2
- ATM | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.53); catalogued as rs147915571, CM056524, COSV53726226, COSV99069705; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATM | c.887A>G p.K296R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs1064795297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.3613C>T p.R1205C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs760928285, COSV53784908; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ATM | c.4972G>A p.A1658T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs372679141; called by muse, mutect2, varscan2
- ATMIN | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs774940449; called by muse, mutect2, varscan2
- ATP10A | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as rs535294000, COSV63521100; called by muse, mutect2, varscan2
- ATP10B | c.2415C>T p.C805= | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as rs760382640; called by muse, mutect2, varscan2
- ATP10B | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs763114091, COSV59144351, COSV59164448; called by muse, mutect2, varscan2
- ATP10B | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1054269099, COSV58777732; called by muse, mutect2, varscan2
- ATP11A | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52106636, COSV99369333; called by muse, mutect2, varscan2
- ATP11A | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs145335126; called by muse, mutect2, varscan2
- ATP12A | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752833147, COSV54514578; called by muse, varscan2
- ATP12A | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs757211146; called by muse, mutect2, varscan2
- ATP13A1 | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs774291606; called by muse, mutect2, varscan2
- ATP13A1 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV52288273; called by muse, mutect2, varscan2
- ATP13A3 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs79760253, COSV99757335; called by muse, mutect2, varscan2
- ATP13A3 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); catalogued as rs753740880, COSV99757300; called by muse, mutect2, varscan2
- ATP13A4 | c.2025G>A p.T675= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as rs200015919; called by muse, varscan2
- ATP1A1 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.201); catalogued as rs141400264; called by muse, mutect2, varscan2
- ATP1B4 | c.395A>G p.Y132C (on ENST00000218008 / NM_001142447.3; = p.Y128C on NM_012069.5) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as rs1287802457, COSV54311798; called by muse, mutect2
- ATP2A1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs182391081, COSV100837047; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B3 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1557004035; called by muse, mutect2, varscan2
- ATP2B3 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs201639064; called by muse, mutect2, varscan2
- ATP2C1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs768289092, COSV60755662; called by muse, mutect2, varscan2
- ATP2C2 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776593054; called by muse, mutect2, varscan2
- ATP4A | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as rs1382227785; called by muse, mutect2, varscan2
- ATP5F1A | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs747589493; called by muse, mutect2, varscan2
- ATP5F1C | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59622381; called by muse, mutect2, varscan2
- ATP6V0D2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs573159453; called by muse, mutect2, varscan2
- ATP6V1B1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs143516810; called by muse, mutect2, varscan2
- ATP6V1H | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV62217452; called by muse, mutect2, varscan2
- ATP7A | c.3734C>A p.S1245Y | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100430727; called by muse, mutect2, varscan2
- ATP7B | c.3787G>A p.A1263T | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781514805, CD115279; called by muse, mutect2, varscan2
- ATP8A1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs556457468, COSV52550248; called by muse, mutect2, varscan2
- ATP8A2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54943115, COSV54966099; called by muse, mutect2, varscan2
- ATP8B1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760934663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP9A | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV58763543; called by muse, varscan2
- ATP9A | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1292946925; called by muse, varscan2
- ATR | c.3431G>A p.G1144D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.975); catalogued as COSV63384685; called by muse, mutect2, varscan2
- ATRN | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs748307870, COSV53523166; called by muse, mutect2, varscan2
- ATRN | c.2518C>T p.R840* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as rs1368168673; called by muse, mutect2, varscan2
- ATRNL1 | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV58076012; called by muse, mutect2, varscan2
- ATRX | c.5216G>A p.R1739Q | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV64874516; called by muse, mutect2, varscan2
- ATXN10 | c.1006C>A p.L336I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV53301102; called by muse, mutect2, varscan2
- ATXN7L3 | c.496A>T p.R166* (on ENST00000389384 / NM_001382309.1; = p.R173* on NM_001382308.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV60228161; called by muse, mutect2, varscan2
- AUTS2 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs777962059, COSV61421405; called by muse, mutect2, varscan2
- AVPR1A | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs750330664; called by muse, mutect2, varscan2
- AXIN2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs878854737; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXL | c.1428G>T p.K476N (on ENST00000301178 / NM_021913.5; = p.K467N on NM_001699.6) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.76); catalogued as COSV56565385, COSV56574626; called by muse, mutect2, varscan2
- AZIN2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745840314, COSV53858928; called by muse, mutect2, varscan2
- B3GALNT1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs765788938; called by muse, mutect2, varscan2
- B3GALNT2 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs1377806467; called by muse, mutect2, varscan2
- B3GALT1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs767958450, COSV59908508; called by muse, mutect2, varscan2
- B3GAT1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1474469932; called by muse, mutect2, varscan2
- B3GAT1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs780492697; called by muse, mutect2, varscan2
- B3GAT1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56997599; called by muse, mutect2, varscan2
- B3GNT4 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs865821692, COSV57336659; called by muse, mutect2, varscan2
- B4GALNT4 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs151090425; called by muse, mutect2, varscan2
- B4GALT3 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758209293; called by muse, mutect2, varscan2
- BAAT | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV52287479; called by muse, varscan2
- BACH1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529204942, COSV99728531; called by muse, mutect2, varscan2
- BACH2 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766960741, COSV57583986, COSV57586999; called by muse, mutect2, varscan2
- BACH2 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs761051258, COSV57588651; called by muse, mutect2, varscan2
- BAG3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs746454994, COSV64841721; called by muse, mutect2, varscan2
- BAG5 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs372348583; called by muse, varscan2
- BAG5 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs762520743; called by muse, varscan2
- BAG5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs757492335, COSV54570293; called by muse, mutect2, varscan2
- BAG6 | c.1930G>A p.A644T (on ENST00000676571; = p.A597T on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1436891981; called by muse, mutect2, varscan2
- BAHCC1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs944741353; called by muse, mutect2
- BAHCC1 | c.5473C>T p.R1825C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs782228993; called by muse, mutect2, varscan2
- BAIAP2 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs745320058, COSV58341782; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99133766; called by muse, mutect2, varscan2
- BAIAP2L1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV99134138; called by muse, mutect2, varscan2
- BAK1 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100645883; called by muse, mutect2, varscan2
- BANP | c.694G>A p.A232T (on ENST00000286122; = p.A201T on NM_017869.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53733911; called by muse, mutect2, varscan2
- BARHL2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1292476644, COSV64981633; called by muse, mutect2, varscan2
- BARX2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs935941057, COSV55649729, COSV55652114; called by muse, mutect2, varscan2
- BAZ2A | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780677811; called by muse, mutect2
- BAZ2A | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs767981157, COSV51640463; called by muse, mutect2, varscan2
- BAZ2B | c.3085C>T p.R1029W | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220985055, COSV54276477; called by muse, mutect2, varscan2
- BBOF1 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63246033; called by muse, mutect2, varscan2
- BBS9 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.014); catalogued as rs778518775; called by muse, mutect2, varscan2
- BBX | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV57883835; called by muse, mutect2, varscan2
- BCAM | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); catalogued as rs754260197; called by muse, mutect2, varscan2
- BCAR1 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751262673, COSV50782805; called by muse, mutect2, varscan2
- BCAR3 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53077075; called by muse, mutect2, varscan2
- BCHE | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52257734; called by muse, mutect2, varscan2
- BCHE | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100012674; called by muse, mutect2, varscan2
- BCL11B | c.2653G>A p.D885N (on ENST00000357195 / NM_001282237.2; = p.D814N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV61734563; called by muse, mutect2, varscan2
- BCL6 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51656676; called by muse, mutect2, varscan2
- BCLAF1 | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); catalogued as rs139492977; called by muse, mutect2
- BCOR | c.4879G>A p.D1627N (on ENST00000378444 / NM_001123385.2; = p.D1593N on NM_017745.6) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs774089771, COSV100652715; called by muse, mutect2, varscan2
- BCORL1 | c.3351G>T p.K1117N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54401630; called by muse, mutect2, varscan2
- BCORL1 | c.4064G>A p.R1355Q | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs141666104; called by muse, varscan2
- BCR | c.3075C>T p.I1025= | Splice Region (SNP) | VAF 58/126 reads (46%) | catalogued as rs771658233, COSV59936558; called by muse, mutect2, varscan2
- BDKRB2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148172749; called by muse, mutect2, varscan2
- BDP1 | c.5530C>T p.R1844C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773389976, COSV62429060; called by muse, mutect2, varscan2
- BECN1 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59311993; called by muse, mutect2, varscan2
- BEND2 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66215585; called by muse, mutect2, varscan2
- BEND3 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs782458566, COSV64680151; called by muse, mutect2, varscan2
- BEST4 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282131552, COSV64733889; called by muse, mutect2, varscan2
- BEX1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as COSV65579974; called by muse, mutect2, varscan2
- BEX3 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | catalogued as COSV55420975; called by muse, mutect2, varscan2
- BEX3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55421170; called by muse, mutect2, varscan2
- BGN | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV59038514; called by muse, mutect2, varscan2
- BHMT2 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.352); catalogued as COSV99670214; called by muse, mutect2, varscan2
- BICC1 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99570891; called by muse, mutect2
- BICD2 | c.633G>T p.E211D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63547985; called by muse, mutect2, varscan2
- BICRAL | c.2113C>A p.L705I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV58408685; called by muse, mutect2
- BIN1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs532260569; called by muse, varscan2
- BIRC6 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV70196094; called by muse, mutect2, varscan2
- BIRC6 | c.5344C>T p.R1782* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs1478448561; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs374998551; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99958434; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs140917545; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2458C>T p.R820* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs966111552; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3277G>T p.E1093* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV63246384; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV63244619; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4225C>A p.L1409I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as rs142856022; called by muse, varscan2
- BIVM-ERCC5 | c.4337G>A p.R1446Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs377390651, COSV63246081; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4822G>A p.D1608N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as rs760309416; called by muse, mutect2, varscan2
- BLK | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980105504; called by muse, varscan2
- BLK | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs1334454883, COSV99377114; called by muse, varscan2
- BLM | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV104422200; called by muse, mutect2, varscan2
- BLOC1S2 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV62489456; called by muse, mutect2, varscan2
- BMP15 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); catalogued as COSV53140217; called by muse, mutect2, varscan2
- BMP2 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544525819; called by muse, mutect2, varscan2
- BMP2K | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200424874, COSV100622018; called by muse, mutect2, varscan2
- BMP5 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144695858; called by muse, mutect2, varscan2
- BNC1 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs141711507; called by muse, mutect2, varscan2
- BNC2 | c.2060C>A p.S687Y | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV66149947; called by muse, varscan2
- BNC2 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.532); catalogued as rs767945913, COSV101034483, COSV66155172; called by muse, mutect2, varscan2
- BNIP3 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as rs746423542, COSV64044096; called by muse, mutect2, varscan2
- BNIPL | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs587607488, COSV54845615; called by muse, mutect2, varscan2
- BOD1 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 43/104 reads (41%) | catalogued as rs1188117543, CM166665; called by muse, mutect2, varscan2
- BOD1L1 | c.9146C>T p.A3049V | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs769512613, COSV50008166; called by muse, mutect2, varscan2
- BORCS5 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as rs932060674, COSV100055935; called by muse, mutect2, varscan2
- BPI | c.695C>A p.S232Y (on ENST00000262865; = p.S228Y on NM_001725.3) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs578216988; called by muse, mutect2, varscan2
- BPNT2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148507660, COSV52907029; called by muse, mutect2, varscan2
- BRAF | c.2323C>T p.R775W (on ENST00000288602 / NM_001374244.1; = p.R735W on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958201; called by muse, mutect2, varscan2
- BRCA2 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as rs1060502376, COSV104430643; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- BRCA2 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV66462281; called by muse, varscan2
- BRCA2 | c.2632G>T p.D878Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV66453135; called by muse, mutect2, varscan2
- BRCA2 | c.4711G>T p.E1571* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | catalogued as COSV101204683; called by muse, varscan2
- BRD1 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758383249, COSV53458619; called by muse, mutect2, varscan2
- BRD4 | c.3919G>A p.A1307T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs748234502; called by muse, mutect2, varscan2
- BRD7 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV67158579; called by muse, mutect2, varscan2
- BRINP1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1335835574, COSV56305906; called by muse, mutect2, varscan2
- BRINP2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV64180724; called by muse, varscan2
- BRINP2 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as rs138839091, COSV64179456; called by muse, varscan2
- BRINP3 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV66513604, COSV66513646; called by muse, mutect2, varscan2
- BRINP3 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV66514384, COSV66531266; called by muse, varscan2
- BRIP1 | c.2477A>G p.N826S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760127237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs375246789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIX1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs374761203; called by mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | catalogued as rs746043904; called by mutect2, varscan2
- BRSK2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV57546056; called by muse, varscan2
- BRWD1 | c.3650G>A p.R1217Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1195115542; called by muse, mutect2, varscan2
- BRWD3 | c.4183C>T p.R1395C | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327577359, COSV64748474; called by muse, mutect2, varscan2
- BSN | c.8504G>A p.R2835H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs147846190; called by muse, mutect2, varscan2
- BTBD11 | c.2513G>A p.R838H (on ENST00000280758 / NM_001018072.2; = p.R375H on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs777803244, COSV55038671; called by muse, mutect2, varscan2
- BTBD11 | c.2716C>T p.R906W (on ENST00000280758 / NM_001018072.2; = p.R443W on NM_001017523.2) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs139566833; called by muse, varscan2
- BTBD11 | c.2732G>A p.R911H (on ENST00000280758 / NM_001018072.2; = p.R448H on NM_001017523.2) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1187196128; called by muse, varscan2
- BTBD6 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs770736236, COSV59271905; called by muse, mutect2, varscan2
- BTBD9 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as rs772386134; called by muse, mutect2, varscan2
- BTG1 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs1479034526, COSV55458261, COSV55460428; called by muse, mutect2, varscan2
- BTK | c.1632G>A p.R544= | Splice Region (SNP) | VAF 26/43 reads (60%) | catalogued as rs1555977496, CM012070; called by muse, mutect2, varscan2
- BTN1A1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs748609018, COSV55068329, COSV55068626; called by muse, mutect2, varscan2
- BTN3A1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.298); catalogued as rs755260389; called by mutect2, varscan2
- BTN3A2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.371); catalogued as rs746878122; called by muse, mutect2, varscan2
- BTNL8 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs1285095329; called by muse, mutect2, varscan2
- BUB1B | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349349252, COSV99807268; called by muse, mutect2, varscan2
- BUD13 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs903586401; called by muse, mutect2, varscan2
- BZW1 | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV63349406; called by muse, mutect2, varscan2
- C10orf90 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs754115635; called by muse, mutect2, varscan2
- C11orf45 | c.110G>T p.R37I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100171578; called by muse, mutect2, varscan2
- C11orf87 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV59359015; called by muse, varscan2
- C12orf40 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as rs867943671; called by muse, mutect2, varscan2
- C12orf71 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV70282598; called by muse, mutect2, varscan2
- C15orf39 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.557); catalogued as rs1389782433; called by muse, mutect2, varscan2
- C16orf70 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772877017; called by muse, mutect2, varscan2
- C17orf75 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1422251488; called by muse, mutect2, varscan2
- C17orf98 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1390841446; called by muse, mutect2, varscan2
- C18orf21 | c.326G>T p.R109I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs751025528; called by mutect2, varscan2
- C18orf25 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750643051, COSV56366839; called by muse, mutect2, varscan2
- C1QC | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs753779937; called by muse, mutect2, varscan2
- C1QTNF4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.28); catalogued as rs767479537; called by muse, mutect2, varscan2
- C1R | c.991G>A p.E331K (on ENST00000536053 / NM_001354346.2; = p.E317K on NM_001733.7) | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs772306231, COSV73293776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1S | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs782484390, COSV61070311; called by muse, mutect2, varscan2
- C1orf109 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as rs777201466; called by muse, varscan2
- C1orf116 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as rs1421435807; called by muse, mutect2, varscan2
- C1orf131 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775969071, COSV59641881; called by muse, varscan2
- C1orf141 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100924331, COSV63993215; called by muse, mutect2, varscan2
- C20orf194 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52695413; called by muse, mutect2, varscan2
- C22orf39 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs754147776, COSV100286961; called by muse, mutect2, varscan2
- C2CD3 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs143645446; called by muse, mutect2, varscan2
- C2CD6 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs201556443; called by muse, mutect2, varscan2
- C2orf16 | c.4724G>A p.R1575H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs747793275; called by muse, mutect2, varscan2
- C2orf78 | c.1880G>A p.G627D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV68518901; called by muse, mutect2, varscan2
- C3 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121909585, CM086785, COSV55568567, COSV55572808; ClinVar: risk factor; called by muse, mutect2, varscan2
- C3 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766179097; called by muse, mutect2, varscan2
- C3orf33 | c.211G>T p.E71* (on ENST00000340171 / NM_001308229.2; = p.E28* on NM_173657.2) | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV60896960; called by muse, mutect2, varscan2
- C5orf22 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745442454, COSV57599943; called by muse, mutect2, varscan2
- C5orf24 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs758397310, COSV57542545; called by muse, mutect2, varscan2
- C8A | c.1367T>A p.V456D | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63485939; called by muse, mutect2, varscan2
- C8G | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs1191718003; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- C8orf74 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as rs561170572; called by muse, mutect2, varscan2
- C9orf64 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs765439002, COSV104406944; called by muse, mutect2, varscan2
- C9orf72 | c.1259+1G>A p.X420_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as rs776218894; called by muse, varscan2
- C9orf72 | c.1220G>T p.R407I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV66163298; called by muse, varscan2
- CA11 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs772181062; called by muse, mutect2, varscan2
- CA11 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as rs777968428; called by muse, mutect2, varscan2
- CA5B | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181134647, COSV100590847, COSV59415674; called by muse, mutect2, varscan2
- CABCOCO1 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs373539789; called by muse, mutect2, varscan2
- CABP5 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs536265470; called by muse, mutect2, varscan2
- CACNA1A | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1208991974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1339761570; called by muse, mutect2, varscan2
- CACNA1B | c.3698C>T p.A1233V | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs756404836, COSV53138126; called by muse, varscan2
- CACNA1C | c.4113C>A p.F1371L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59717484; called by muse, mutect2, varscan2
- CACNA1D | c.4663C>T p.R1555* (on ENST00000350061 / NM_001128840.3; = p.R1575* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs562123739, COSV55466685; called by muse, mutect2, varscan2
- CACNA1D | c.5126G>A p.R1709H (on ENST00000350061 / NM_001128840.3; = p.R1729H on NM_000720.4) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs568343967; called by muse, varscan2
- CACNA1D | c.5204C>T p.S1735L (on ENST00000350061 / NM_001128840.3; = p.S1755L on NM_000720.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1461261149, COSV55437928; called by muse, varscan2
- CACNA1E | c.4132C>A p.L1378M | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62383190; called by muse, mutect2, varscan2
- CACNA1F | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59905832; called by muse, mutect2, varscan2
- CACNA1F | c.2394G>T p.E798D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100544371; called by mutect2, varscan2
- CACNA1H | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs746748953, COSV61996628, COSV61996721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.3473C>A p.T1158N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62936273; called by muse, mutect2, varscan2
13,429 further variants in this file (9,862 protein-altering or splice-affecting, 3,223 silent, 344 other) are not listed here.
